Gene-level copy-number profile of tumor specimen TCGA-CR-7369-01A from TCGA case TCGA-CR-7369, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 60.0 years (21,897 days).
Specimen TCGA-CR-7369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8f792d9a-0982-44df-9c36-566c2abeab3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7369-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/997eaefd-351f-4a81-97cf-9cc50a4e11e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 137; copy number 1: 12,802; copy number 2: 42,278; copy number 3: 4,100; copy number 4: 417; copy number 5: 52; copy number 7: 2; copy number 15: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7369-01A-11D-2128-01): tumor purity 0.53, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,691,821, 2 genes: AL591848.2, AL591848.1.
- chr17:19,189,665–21,641,536, 134 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 74 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,238,686–189,240,594, 1 gene, copy number 5: TPRG1-AS2.
- chr8:84,162,118–85,087,186, 10 genes, copy number 5: TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1.
- chr11:69,985,876–71,863,658, 60 genes, copy number 5–15: AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, AP000867.4, RPS3AP41, ALG1L9P, SNRPCP14, AP003498.1, ENPP7P8, AP003498.2, FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C.
- chr11:71,878,453–71,884,561, 1 gene, copy number 5: DEFB131B.
- chr13:73,399,031–73,408,352, 2 genes, copy number 7: AL162376.1, MARK2P12.

Autosomal genes at a single copy (total copy number 1): 10,423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
